Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q5-06A (Metastatic).

[page 1 of 2]
100-6-3

Melanoma, nos 8720/3

Site: lymph node, nos C77.9
3/15/11 *hw*

DIAGNOSIS

(A) LEFT BREAST, SKIN AND SUBCUTANEOUS TISSUE ELLIPSE:

SCAR AND MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE, EXCISION, MARGINS FREE OF MELANOMA.

TUMOR SIZE IS 14.0 X 12.0 MM.

TUMOR EXHIBITS PUSHING BORDERS.

(SEE COMMENT.)

(B) LEFT AXILLARY CONTENTS:

METASTATIC MALIGNANT MELANOMA IN 1 OF 12 LYMPH NODES (1/12).

TUMOR SIZE IS 60.0 X 50.0 MM.

TUMOR IS SUBCAPSULAR AND INTRAPARENCHYMAL.

Extracapsular extension is not identified.

(C) ADDITIONAL LEVEL 2 AND 3 LYMPH NODES:

Twelve lymph nodes, no melanoma identified (0/12).

(D) APEX OF LEFT AXILLA:

Two lymph nodes, no melanoma identified (0/2).

Site/AA Discrepancy		

Entire report and diagnosis completed by

MD

COMMENT

(A) Based on the histological findings, a recurrent or metastatic origin are possible. Clinical-pathologic correlation is necessary.

GROSS DESCRIPTION

(A) RESECTION RECURRENT MELANOMA OF LEFT BREAST WITH PREVIOUS SCAR (SHORT SUPERIOR, LONG LATERAL) - A tan-white skin ellipse, 10.8 x 4.7 cm, excised with subcutaneous tissue up to a depth of 3.5 cm. A short suture designates the superior margin and the long suture designates the lateral tip. The central portion of the skin shows an irregular scar, 5.0 x 1.1 cm. The nipple is identified midportion of the specimen close to the inferior margin. Serial sectioning reveals a tan-white well-circumscribed nodule, 1.4 x 1.2 x 1.2 cm, focally adherent to the overlying skin. The nodule is about 1.5 cm from the nearest margin which is the superior margin. The entire scar together with the underlying nodule is submitted for examination.

INK CODE: Superior half-blue; inferior half-yellow.

SECTION CODE: A1, lateral tip; A2-A13, scar with underlying lesion (A4-A6, mass lesion, A2, A3, A10-A13, remainder of the scar without obvious lesion); A14, medial tip; A15, superior margin, en face; A16, inferior margin, en face; A17, deep margin, en face; A18, A19, entire nipple with adjacent margin (the nipple is grossly unremarkable). NOTE: margins not included in sections A2 to A13. MN1/beg

(B) LEFT AXILLARY CONTENTS WITHIN CONTINUITY SUBSEQUENT TISSUE LEFT BREAST - One piece of axillary contents with a large mass. The specimen measures 15.0 x 14.0 x 4.0 cm. The largest metastatic tumor measures 6.0 x 5.0 x 5.0 cm. The cut surface of the largest mass is white-tan and firm. Multiple small lymph nodes ranging from 0.3 to 2.0 cm are identified. Sections from the largest metastatic lesion are submitted in cassette B1-B6 to evaluate possible extranodal extension.

The remainder of the pink-tan fibrosis adipose tissue is serially sectioned. Twelve lymph nodes are identified ranging in size from 0.6 x 0.6 x 0.6 cm to 2.0 x 2.0 x 1.0 cm.

[page 2 of 2]
SECTION CODE: B7, two possible lymph nodes; B8, one lymph node; B9, one lymph node; B10, one lymph node; B11, one lymph node; B12, one lymph node; B13, one lymph node; B14-B15, one lymph node; B16-B17, one lymph node; B18-B19, one lymph node; B20-B21, one lymph node.

(C) ADDITIONAL LEVEL 2 AND 3 LYMPH NODES - An irregular fragment of adipose tissue measuring 6.0 x 5.0 x 1.0 cm. The specimen is serially sectioned and thirteen lymph nodes are identified ranging in size from (0.4 x 0.3 x 0.3 to 1.5 x 1.0 x 0.6 cm).

SECTION CODE: C1, one lymph node bisected; C2, three possible lymph nodes; C3, three lymph nodes; C4, two lymph nodes; C5, two lymph nodes; C6, one lymph nodes bisected; C7, one lymph node bisected.

(D) APEX OF LEFT AXILLA - Two lymph nodes measuring 0.3 x 0.2 x 0.2 and 2.0 x 1.0 x 0.5 cm.

SECTION CODE: D1, one lymph node bisected; D2, one lymph node.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by I Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file fef401af-b0c5-405d-bd29-244205fc271f (TCGA-D3-A1Q5.0BF62172-ADA2-4078-AEBD-C0FC71F4A8E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).